Surgical pathology report (de-identified scan), TCGA case TCGA-BR-4256, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-4256-01A (Primary Tumor).

STOMACH TISSUE CHECKLIST. Specimen type: Gastrectomy. Tumor Site: Antrum. Tumor configuration: Ulcerating. Tumor size: 7 x 3 x 0.5 cm. Histologic type: Adenocarcinoma. Histologic grade: Moderately differentiated. Extent of invasion: Not specified. Lymph nodes: 3 of 8 positive for metastasis. Margins – Proximal margin: Not specified. Distal margin: Not specified. Omental (radial) margin: Not specified. Lymphatic invasion: Not specified. Venous invasion: Not specified. Perineural invasion: Not specified. Additional pathologic findings: Not specified. Comments: None.

Source: NCI Genomic Data Commons file 264f0b73-52cf-4c16-a4f2-1392119fa9e5 (TCGA-BR-4256.439F5D46-BF7A-4194-8668-D71A25250665.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).